Somatic mutation profile of tumor specimen TCGA-HW-7491-01A (aliquot TCGA-HW-7491-01A-11D-2024-08) from TCGA case TCGA-HW-7491, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 35.2 years (12,874 days).
Specimen TCGA-HW-7491-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8cf5639c-ed30-4a0a-acc1-840b7e7024e2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HW-7491-10A (Blood Derived Normal), aliquot TCGA-HW-7491-10A-01D-2024-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/56b55c3f-3ca0-4a09-bed1-0da01542cf6c

The open-access MAF lists 15 somatic variants for this specimen: 12 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 9, Silent 3, In Frame Del 1, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CIC | c.643C>T p.R215W | Missense Mutation (SNP) | VAF 37/47 reads (79%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1568504941, COSV50547203; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- IDH2 | c.515G>A p.R172K | Missense Mutation (SNP) | VAF 35/66 reads (53%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs121913503, COSV57468734, COSV57468971, COSV57472976; ClinVar: pathogenic / not provided / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.328_330del p.E110del | In Frame Del (DEL) | VAF 39/90 reads (43%) | hotspot (GDC flag); called by pindel, varscan2
- AGPS | c.1741T>G p.F581V | Missense Mutation (SNP) | VAF 39/116 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); catalogued as COSV51565574; called by muse, mutect2, varscan2
- LAMB4 | c.540C>A p.D180E | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.471); catalogued as COSV52722334; called by muse, mutect2, varscan2
- PSMD4 | c.388C>T p.R130C | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.077); catalogued as rs749225884, COSV64393104; called by muse, mutect2
- SLITRK6 | c.296A>G p.N99S | Missense Mutation (SNP) | VAF 79/100 reads (79%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV101233188, COSV68390511; called by muse, mutect2, varscan2
- TRIM9 | c.1780C>G p.P594A | Missense Mutation (SNP) | VAF 45/104 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV53619183; called by muse, mutect2, varscan2
- TTC7A | c.785G>A p.R262K | Missense Mutation (SNP) | VAF 49/104 reads (47%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV55412271; called by muse, mutect2, varscan2
- VPS13A | c.5752G>A p.D1918N | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV62432189; called by muse, mutect2, varscan2
- FUT5 | c.389_390dup p.S131Pfs*118 | Frame Shift Ins (INS) | VAF 17/59 reads (29%) | called by mutect2, pindel, varscan2
- SLC12A4 | c.676-12_677del p.X226_splice | Splice Site (DEL) | VAF 22/112 reads (20%) | called by mutect2, pindel, varscan2
- DVL2 | c.801A>G p.T267= | Silent (SNP) | VAF 41/101 reads (41%) | catalogued as rs1451512425, COSV50036753; called by muse, mutect2, varscan2
- OR6Q1 | c.576G>A p.S192= | Silent (SNP) | VAF 69/133 reads (52%) | catalogued as rs528605468, COSV100110351, COSV56933574; called by muse, mutect2, varscan2
- SCN10A | c.4917C>T p.D1639= | Silent (SNP) | VAF 77/153 reads (50%) | catalogued as rs142804903; called by muse, mutect2, varscan2
